Somatic mutation profile of tumor specimen MMRF_2681_1_BM_CD138pos (aliquot MMRF_2681_1_BM_CD138pos_T1_KHS5U_L14251) from MMRF case MMRF_2681, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 45.2 years (16,513 days).
Specimen MMRF_2681_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d479ba65-7338-429c-b143-32813faa2473.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2681_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2681_1_PB_WBC_C3_KHS5U_L14252; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/37664c9f-1898-4cd6-84a0-6fd0a0c714cc

The open-access MAF lists 72 somatic variants for this specimen: 32 protein-altering or splice-affecting, 10 silent, 30 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, 3'UTR 15, Silent 10, 5'UTR 5, Intron 5, 3'Flank 3, RNA 1, 5'Flank 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 21/25 reads (84%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- AKR1D1 | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as rs777588168; called by muse, mutect2, varscan2
- AOC2 | c.1835C>A p.P612H | Missense Mutation (SNP) | VAF 59/150 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs754956944; called by muse, mutect2, varscan2
- DEPDC5 | c.2984G>T p.S995I (on ENST00000400246; = p.S1064I on NM_014662.5) | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.16); catalogued as COSV56711438; called by muse, mutect2, varscan2
- EFCAB7 | c.1035T>A p.F345L | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.43); catalogued as COSV100391326; called by muse, mutect2, varscan2
- IGHV2-70D | c.274A>G p.K92E | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); catalogued as rs1451105528; called by muse, varscan2
- IGLL5 | c.161C>A p.A54D | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs762998471, COSV73248971, COSV73251039; called by muse, mutect2, varscan2
- IGLV3-1 | c.247T>C p.S83P | Missense Mutation (SNP) | VAF 103/229 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs377587177; called by muse, varscan2
- MAML2 | c.2161C>G p.Q721E | Missense Mutation (SNP) | VAF 68/152 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.428); catalogued as rs999381774; called by muse, mutect2, varscan2
- MTHFD2 | c.572C>T p.T191I | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as rs758874646; called by muse, mutect2, varscan2
- MYH14 | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1218671199, COSV99222676; called by muse, mutect2
- OR52A1 | c.398G>C p.R133T | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV61092754; called by muse, mutect2, varscan2
- PARD6G | c.1066C>T p.P356S | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.335); catalogued as rs1311462763; called by muse, mutect2, varscan2
- SASH1 | c.160G>A p.G54S | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.826); catalogued as rs937939084; called by muse, mutect2
- TRIO | c.2120A>T p.Q707L | Missense Mutation (SNP) | VAF 63/156 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV60088390; called by muse, mutect2, varscan2
- BECN1 | c.1340T>G p.F447C | Missense Mutation (SNP) | VAF 97/192 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BTBD17 | c.877C>T p.H293Y | Missense Mutation (SNP) | VAF 70/166 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- BTBD17 | c.799C>T p.Q267* | Nonsense Mutation (SNP) | VAF 88/175 reads (50%) | called by muse, mutect2, varscan2
- CENPE | c.1343C>A p.T448K | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- CHD5 | c.5280G>T p.Q1760H | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CREBBP | c.4890+1G>T p.X1630_splice | Splice Site (SNP) | VAF 20/57 reads (35%) | called by muse, mutect2, varscan2
- DNAH10 | c.11554C>A p.L3852I (on ENST00000409039; = p.L3791I on NM_207437.3) | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- FUT9 | c.410A>T p.E137V | Missense Mutation (SNP) | VAF 134/289 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HTR4 | c.1126G>T p.V376F | Missense Mutation (SNP) | VAF 22/553 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.089); called by muse, mutect2
- IBTK | c.1131G>T p.L377F | Missense Mutation (SNP) | VAF 140/298 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- METTL8 | c.725A>T p.H242L | Missense Mutation (SNP) | VAF 22/284 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- PRKD2 | c.1328T>C p.L443P | Missense Mutation (SNP) | VAF 103/264 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRL | c.288C>A p.D96E | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PSMD4 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 65/135 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- TCL1A | c.119A>G p.E40G | Missense Mutation (SNP) | VAF 134/202 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.394); called by muse, varscan2
- TRERF1 | c.2878G>C p.E960Q | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- ZNF653 | c.1765G>T p.D589Y | Missense Mutation (SNP) | VAF 67/155 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- ACKR2 | c.522C>T p.A174= | Silent (SNP) | VAF 78/188 reads (41%) | called by muse, mutect2, varscan2
- BTBD17 | c.484C>T p.L162= | Silent (SNP) | VAF 48/95 reads (51%) | called by muse, mutect2, varscan2
- CMYA5 | c.1287T>C p.S429= | Silent (SNP) | VAF 12/214 reads (6%) | called by muse, mutect2
- OR10P1 | c.183C>T p.F61= | Silent (SNP) | VAF 36/293 reads (12%) | called by muse, mutect2, varscan2
- OR10P1 | c.522C>T p.I174= | Silent (SNP) | VAF 55/468 reads (12%) | catalogued as COSV59006921; called by muse, mutect2, varscan2
- PANX3 | c.1114T>C p.L372= | Silent (SNP) | VAF 16/274 reads (6%) | catalogued as rs1266397974; called by muse, mutect2
- SRSF4 | c.165G>A p.L55= | Silent (SNP) | VAF 108/222 reads (49%) | called by muse, varscan2
- TMTC1 | c.520C>T p.L174= (on ENST00000539277 / NM_001193451.2; = p.L66= on NM_175861.3) | Silent (SNP) | VAF 67/162 reads (41%) | called by muse, mutect2, varscan2
- USH2A | c.8547A>T p.G2849= | Silent (SNP) | VAF 41/76 reads (54%) | called by muse, mutect2, varscan2
- WNK2 | c.5907C>T p.P1969= (on ENST00000297954 / NM_001282394.1; = p.P1932= on NM_006648.3) | Silent (SNP) | VAF 53/126 reads (42%) | catalogued as rs753972546; called by muse, mutect2, varscan2
- C1QTNF4 | c.*37C>T | 3'UTR (SNP) | VAF 26/71 reads (37%) | called by muse, mutect2, varscan2
- C4A | chr6:32006832 A>G | 3'Flank (SNP) | VAF 97/228 reads (43%) | called by muse, mutect2, varscan2
- CPLX4 | c.*1111T>G | 3'UTR (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- DTX1 | chr12:113057688 A>C | 5'Flank (SNP) | VAF 9/14 reads (64%) | called by muse, mutect2, varscan2
- HLX | chr1:220879441 CTATTACT>TATTAC | 5'UTR (DEL) | VAF 4/44 reads (9%) | called by pindel, varscan2*
- IGHV3-23 | c.-77C>G | 5'UTR (SNP) | VAF 7/26 reads (27%) | called by muse, mutect2, varscan2
- ISL2 | c.*282G>T | 3'UTR (SNP) | VAF 59/143 reads (41%) | called by muse, mutect2, varscan2
- KCNA6 | c.-371G>A | 5'UTR (SNP) | VAF 63/72 reads (88%) | called by muse, mutect2, varscan2
- KIF1A | c.*1983C>A | 3'UTR (SNP) | VAF 64/162 reads (40%) | called by muse, varscan2
- LSM5 | c.243+10A>T | Intron (SNP) | VAF 88/237 reads (37%) | called by muse, mutect2, varscan2
- MAP3K2 | chr2:127304095 A>G | 3'Flank (SNP) | VAF 38/91 reads (42%) | called by muse, mutect2, varscan2
- MICAL3 | c.*1842A>T | 3'UTR (SNP) | VAF 176/371 reads (47%) | called by muse, mutect2, varscan2
- MON2 | chr12:62603687 T>A | 3'Flank (SNP) | VAF 28/72 reads (39%) | called by muse, mutect2, varscan2
- NFIB | c.*4480G>T | 3'UTR (SNP) | VAF 65/138 reads (47%) | called by muse, mutect2, varscan2
- NMNAT1 | c.*447T>C | 3'UTR (SNP) | VAF 8/31 reads (26%) | called by muse, mutect2, varscan2
- NRIP2 | c.*1554A>T | 3'UTR (SNP) | VAF 12/302 reads (4%) | called by muse, mutect2
- PCLO | c.13655-1660A>C | Intron (SNP) | VAF 45/92 reads (49%) | called by muse, mutect2, varscan2
- PIP4K2B | c.*1315G>T | 3'UTR (SNP) | VAF 31/245 reads (13%) | called by muse, varscan2
- RHOBTB3 | c.1720+88G>T | Intron (SNP) | VAF 15/37 reads (41%) | called by muse, mutect2, varscan2
- SDHAP3 | n.25G>A | RNA (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2, varscan2
- SETD7 | c.*4688C>T | 3'UTR (SNP) | VAF 85/169 reads (50%) | called by muse, mutect2, varscan2
- SLA | c.*317G>C | 3'UTR (SNP) | VAF 22/207 reads (11%) | called by muse, mutect2, varscan2
- SLITRK3 | c.*654A>C | 3'UTR (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- SYNE2 | c.19334-588G>A | Intron (SNP) | VAF 17/95 reads (18%) | called by muse, mutect2, varscan2
- TENT5C | c.*2143T>C | 3'UTR (SNP) | VAF 30/88 reads (34%) | called by muse, mutect2, varscan2
- TMCC1 | c.*2642C>T | 3'UTR (SNP) | VAF 46/98 reads (47%) | called by muse, mutect2, varscan2
- WDR12 | c.-122C>T | 5'UTR (SNP) | VAF 36/84 reads (43%) | catalogued as rs980317414, COSV99651170; called by muse, mutect2, varscan2
- ZNF282 | c.*1457G>A | 3'UTR (SNP) | VAF 8/194 reads (4%) | catalogued as rs997330074; called by muse, mutect2
- ZNF300 | c.265+76C>T | Intron (SNP) | VAF 117/256 reads (46%) | catalogued as rs1418059574; called by muse, mutect2, varscan2
- ZNF90 | c.-111G>C | 5'UTR (SNP) | VAF 60/134 reads (45%) | called by muse, mutect2, varscan2
